Gene-level copy-number profile of tumor specimen TARGET-40-0A4I0W-01A from TARGET case TARGET-40-0A4I0W, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 20.1 years (7,330 days).
Specimen TARGET-40-0A4I0W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.d87598b3-ed09-5dde-b303-4c5f1e4316ba.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I0W-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 360 have no estimate.
https://portal.gdc.cancer.gov/files/a375c4a9-2d98-4fc7-923e-b9b57e2ca824

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 2,306; copy number 2: 15,803; copy number 3: 17,104; copy number 4: 18,284; copy number 5: 1,066; copy number 6: 4,364; copy number 7: 416; copy number 8: 775; copy number 9: 4; copy number 10: 69; copy number 11: 43; copy number 13: 6; copy number 19: 5.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:21,464,700–21,464,758, 1 gene: MIR7978.
- chr12:9,480,608–9,576,275, 2 genes (within-gene range 0–3): AC092821.1, AC092821.2.
- chr16:46,469,341–46,626,992, 7 genes (within-gene range 0–1): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1.
- chr17:7,613,946–7,711,372, 6 genes: SHBG, SAT2, ATP1B2, TP53, WRAP53, EFNB3.
- chr19:43,211,791–43,269,530, 2 genes (within-gene range 0–3): CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 127 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:177,309,874–178,406,830, 11 genes, copy number 13–19: NEIL3, AC027627.1, AGA, AC078881.1, RNA5SP172, AC103879.1, LINC01098, LINC01099, RNU1-45P, AC095041.1, RNA5SP173.
- chr6:69,672,757–72,523,238, 43 genes, copy number 11: LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3, LYPLA1P3, RNU6-411P, AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P, RIMS1, AL035633.1, FO393414.2.
- chr9:80,563,571–80,871,295, 4 genes, copy number 9: MTCO1P51, MTND2P9, RPS19P6, AL138749.1.
- chr18:11,326,270–13,125,052, 69 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 154. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
